Somatic mutation profile of tumor specimen TCGA-TS-A8AY-01A (aliquot TCGA-TS-A8AY-01A-21D-A39R-32) from TCGA case TCGA-TS-A8AY, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 49.0 years (17,894 days).
Specimen TCGA-TS-A8AY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f8651c1-b882-4bf2-8eea-742bc1896681.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TS-A8AY-10A (Blood Derived Normal), aliquot TCGA-TS-A8AY-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64f525a9-eb4c-4f9c-9915-b877df0f38b9

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Splice Region 1, Frame Shift Ins 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP4 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768149014; called by muse, mutect2, varscan2
- ACOT13 | c.421dup p.*141Lfs*18 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | called by mutect2, varscan2
- COP1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DSEL | c.1725A>T p.R575S | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MCF2 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTMR3 | c.925_939del p.P309_L313del | In Frame Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- MYH9 | c.1368C>G p.F456L | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PAPPA2 | c.5272T>A p.C1758S | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAD18 | c.1279A>G p.I427V | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- RANBP3L | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- TCIM | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNIK | c.639G>A p.K213= | Splice Region (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- USP4 | c.612T>A p.D204E | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CCND1 | c.429C>G p.L143= | Silent (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2, varscan2
- MMP16 | c.1764G>A p.K588= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs968847839, COSV54154373; called by muse, mutect2, varscan2
- TMEM184B | c.426G>A p.S142= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs780169789; called by muse, mutect2, varscan2
- BIRC8 | n.1517C>T | RNA (SNP) | VAF 50/156 reads (32%) | catalogued as rs779949742; called by muse, mutect2, varscan2
